Surgical pathology report (de-identified scan), TCGA case TCGA-CV-A6JU, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-A6JU-01A (Primary Tumor).

[page 1 of 5]
F

(159.0cm 39.3kg BSA: 1.32m²)

Accession:

Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

(A) LEFT AE FOLD:

Squamous mucosa with mild dysplasia

(B) RIGHT NECK SENTINEL LYMPH NODE #1:

Two lymph nodes, negative for tumor (0/2).

(C) RIGHT NECK, SENTINEL LYMPH NODE #2:

One lymph node, negative for tumor (0/1).

(D) RIGHT NECK DISSECTION, LEVEL IB:

Two lymph nodes, negative for tumor (0/2).

(E) RIGHT SENTINEL LYMPH NODE #3:

One lymph node, negative for tumor (0/1).

(F) RIGHT NECK DISSECTION, LEVEL IIB:

Three lymph nodes, negative for tumor (0/3).

(G) RIGHT SENTINEL LYMPH NODE #4, LEVEL III:

One lymph node, negative for tumor (0/1).

(H) RIGHT SENTINEL LYMPH NODE #5:

One lymph node, negative for tumor (0/1).

(I) RIGHT NECK DISSECTION, LEVEL IIA AND IIB:

Seventeen lymph nodes, negative for tumor (0/17).

(J) RIGHT NECK DISSECTION, LEVEL III:

Eleven lymph nodes, negative for tumor (0/11).

(K) RIGHT NECK DISSECTION, LEVEL IV:

Two lymph nodes, negative for tumor (0/2).

(L) RIGHT SENTINEL LYMPH NODE #6, LEVEL IV:

One lymph node, negative for tumor (0/1).

(M) LEFT PAROTID LYMPH NODE:

One lymph node, negative for tumor (0/1).

(N) LEFT NECK, LEVEL IIA, SENTINEL LYMPH NODE #7:

One lymph node, negative for tumor (0/1).

(O) SENTINEL LYMPH NODE #8, LEFT NECK, LEVEL III:

One lymph node, negative for tumor (0/1).

(P) LEFT NECK DISSECTION, LEVEL II:

Fourteen lymph nodes, negative for tumor (0/14).

(Q) PORTION OF FATTY TISSUE:

ICD-O-3

Carcinoma, squamous
cell NOS 8070/3

Site: Tongue NOS 202.9

8/9/13

[page 2 of 5]
Accession:

F

(159.0cm 39.3kg BSA: 1.32m²)

Specimen Date/Time:

Fifteen lymph nodes, negative for tumor (0/15).

(R) LEFT NECK DISSECTION, LEVEL IV:

Five lymph nodes, negative for tumor (0/5).

(S) LEFT NECK, LEVEL II, SENTINEL LYMPH NODE #9:

One lymph node, negative for tumor (0/1).

(T) LEFT NECK, LEVEL II, SENTINEL LYMPH NODE #10:

One lymph node, negative for tumor (0/1).

(U) LEFT NECK, LEVEL III, SENTINEL LYMPH NODE #11:

One lymph node, negative for tumor (0/1).

(V) COMPOSITE RESECTION MANDIBLE FLOOR OF MOUTH AND TONGUE:

INVASIVE SQUAMOUS CARCINOMA -- Moderately differentiated

Tumor Features:

Gross: Ulcerating

Size: 2.5 cm in largest dimension

Invasion: Present, depth 1.5 cm

Tumor Border: Infiltrative with thin cords < 4 cells

Perineural Invasion: Present, Extensive

Vascular Invasion: Absent

Bone / Cartilage Invasion: Pending Decalcification (see addendum)

Eleven lymph nodes, negative for carcinoma (0/11).

(W) LEFT POSTERIOR TONGUE MARGIN, TRUE MARGIN INKED:

Skeletal muscle and salivary gland tissue, negative for tumor.

(X) POSTERIOR DEEP TONGUE:

Skeletal muscle, negative for tumor.

(Y) LEFT MYOHYOID:

Skeletal muscle, negative for tumor.

(Z) DIGASTRIC MUSCLE:

Skeletal muscle and adipose tissue, negative for tumor.

GROSS DESCRIPTION

(A) LEFT AE FOLD - A single fragment of tan-pink soft tissue (0.4 cm) that is submitted entirely in A.

(B) RIGHT NECK SENTINEL LYMPH NODE #1 - Two possible lymph nodes, 1.2 x 0.8 x 0.6 cm and 1.5 x 0.8 x 0.4 cm.

SECTION CODE: A smaller lymph node is designated as B1 and the larger lymph node will be designated as B2. Lymph nodes are serially sectioned and submitted entirely. Smaller lymph node submitted in cassette B1. Larger lymph node submitted in cassette B2.

(C) RIGHT NECK, SENTINEL LYMPH NODE #2 - One possible lymph node (0.5 x 0.5 x 0.4 cm) that is bisected and submitted entirely in C.

(D) RIGHT NECK DISSECTION, LEVEL IB - One piece of fibroadipose tissue with attached salivary gland overall (3.6 x 2.8 x 1.4 cm) yielding four possible lymph nodes ranging from 0.2 to 0.8 cm and salivary gland tissue (3.1 x 2.7 x 1.1 cm).

SECTION CODE: D1, one possible lymph node; D2, one possible lymph node bisected; D3, one possible lymph node bisected; D4, one possible lymph node; D5-D8, salivary gland submitted in toto.

(E) RIGHT SENTINEL LYMPH NODE #3 - One possible lymph node (0.9 x 0.7 x 0.5 cm) that is trisected and submitted entirely in E.

[page 3 of 5]
Accession:
Specimen Date/Time:

F (159.0cm 39.3kg BSA: 1.32m²)

(F) RIGHT NECK DISSECTION, LEVEL IIB - Three possible lymph nodes ranging in greatest dimension from 0.4 to 0.7 cm.
SECTION CODE: F1, three possible lymph nodes.

(G) RIGHT SENTINEL LYMPH NODE #4, LEVEL III - One possible lymph node (0.6 x 0.2 x 0.2 cm) that is trisected and submitted entirely submitted in G.

(H) RIGHT SENTINEL LYMPH NODE #5 - One possible lymph node (1.0 x 0.7 x 0.4 cm) that is serially sectioned and submitted entirely in H.

(I) RIGHT NECK DISSECTION, LEVEL IIA AND II B - A piece of fibroadipose tissue (5.3 x 2.5 x 0.8 cm).
SECTION CODE: I1, one possible node bisected; I2, one possible lymph node bisected; I3, one possible lymph node

bisected; I4, one possible lymph node bisected; I5, one possible lymph node bisected; I6, five possible lymph nodes; I7, five possible lymph nodes; I8, two possible lymph nodes; I9, two possible lymph nodes.

(J) RIGHT NECK DISSECTION, LEVEL III - Two pieces of fibroadipose tissue (4.5 x 2.8 x 0.8 cm and 2.5 x 3.0 x 0.4 cm) yielding eleven possible lymph nodes ranging in greatest dimension from 0.1 to 1.1 cm.

SECTION CODE: J1, three lymph nodes; J2, eight possible lymph nodes; J3, one lymph node bisected.

(K) RIGHT NECK DISSECTION, LEVEL IV - One piece of fibroadipose tissue (2.8 x 2.0 x 0.6 cm) yielding one possible lymph node (0.5 x 0.4 x 0.4 cm).

SECTION CODE: K1, one possible lymph node; K2, K3, remaining fibroadipose tissue submitted in toto.

(L) RIGHT SENTINEL LYMPH NODE #6, LEVEL IV - One possible lymph node (0.6 x 0.5 x 0.3 cm) that is trisected and submitted entirely in L.

(M) LEFT PAROTID LYMPH NODE - One possible lymph node (1.5 x 0.5 x 0.4 cm) that is submitted entirely in M.

(N) LEFT NECK, LEVEL IIA SENTINEL LYMPH NODE #7 - One possible lymph node (1.1 x 1.1 x 0.7 cm) that is serially sectioned and is submitted entirely in N.

(O) SENTINEL LYMPH NODE #8 LEFT NECK, LEVEL III - One possible lymph node (0.9 x 0.7 x 0.4 cm) that is trisected and submitted entirely in O.

(P) LEFT NECK DISSECTION LEVEL II - A portion of fatty tissue (4.0 x 3.0 x 1.7 cm) that is dissected to reveal fourteen possible lymph nodes ranging from 0.1 up to 1.5 cm in greatest dimension. Lymph nodes submitted entirely.
SECTION CODE: P1, five possible lymph nodes; P2, five possible lymph nodes; P3, four lymph nodes.

(Q) PORTION OF FATTY TISSUE - A 3.5 x 2.0 x 1.5 cm that is dissected to reveal fifteen possible lymph nodes ranging from 0.2 up to 1.5 cm in greatest dimension. Lymph nodes submitted entirely.
SECTION CODE: Q1, five possible lymph nodes; Q2, five possible lymph nodes; Q3, five lymph nodes.

(R) LEFT NECK DISSECTION LEVEL IV - A portion of fatty tissue (3.5 x 3.1 x 1.2 cm) that is dissected to reveal five possible lymph nodes ranging from 0.2 up to 1.3 cm in greatest dimension. Lymph nodes submitted entirely.
SECTION CODE: R1, four possible lymph nodes; R2, one possible lymph node, bisected.

(S) LEFT NECK, LEVEL II SENTINEL LYMPH NODE #9 - A pale pink fragment of possible lymph node (0.5 x 0.4 x 0.3 cm). The specimen is bisected and submitted in toto in cassette S1.

(T) LEFT NECK, LEVEL II, SENTINEL LYMPH NODE #10 - A lymph node (0.6 x 0.6 x 0.4 cm), serially sectioned and submitted in toto in T1.

(U) LEFT NECK, LEVEL III, SENTINEL LYMPH NODE #11 - A single lymph node (1.0 x 0.7 x 0.4 cm), serially sectioned and submitted entirely in U1.

(V) COMPOSITE RESECTION MANDIBLE FLOOR OF MOUTH AND TONGUE - A partial left mandibulectomy and left tongue and floor of mouth (13.0 x 4.0 x 3.5 cm overall). There is a light tan, firm infiltrating mass (2.5 x 2.0 x 1.5 cm) located in the center of the left side of the tongue and extends to the base of tongue. The margins of resection are grossly uninvolved. The closest margin is the posteroinferior aspect of the tongue (0.3 cm). The remainder of the specimen is sent to the bone lab for decalcification and further processing.

SECTION CODE: V1, frozen section; V2-V15, representative sections of tongue from anterior to posterior; V16, two possible lymph nodes; V17-V18, one bisected node in each cassette; V19-V22, remainder of surrounding adipose tissue; V23, anterior mandible resection margin, en face for decalcification; V24, posterior mandible resection margin, en face for decalcification; V25-V27, representative sections of possible tumor to mandible bone submitted for decalcification.

*FS/DX: DEEP MEDIAL MARGIN, FREE OF TUMOR.

(W) LEFT POSTERIOR TONGUE MARGIN, TRUE MARGIN INKED - A portion of tan, maroon tissue (2.8 x 0.9 x 1.8 cm). The specimen is inked at one edge. The specimen is bisected along its length and the true margin is submitted ink side down, en face, for frozen section.

INK CODE: Blue - true margin.

SECTION CODE: W1, true margin, en face, for frozen section. W2, remainder of the specimen.

*FS/DX: NO TUMOR PRESENT.

(X) POSTERIOR DEEP TONGUE - Two fragments of tan-pink soft tissue, both measuring 0.7 cm in greatest dimension. The

[page 4 of 5]
Accession: F (159.0cm 39.3kg BSA: 1.32m²)
Specimen Date/Time:

specimen is submitted entirely in X.

(Y) LEFT MYOHYOID – Two fragments of tan-pink skeletal muscle (0.5 and 1.4 cm in greatest dimension). Specimen is submitted entirely in Y.

(Z) DIGASTRIC MUSCLES – A portion of skeletal muscle (3.0 x 3.0 x 1.0 cm), that is serially sectioned to reveal unremarkable cut surfaces. Representative sections are submitted in Z.

CLINICAL HISTORY

SNOMED CODES

T-53000, T-11180, T-C4200, M-80703,

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by:

Start of ADDENDUM

[page 5 of 5]
Accession:
Specimen Date/Time:

159.6cm 30.3kg BSA: 1.32m²

ADDENDUM

This modified report is being issued to report the results of decalcification.

Addendum completed by

DIAGNOSIS

(V) COMPOSITE RESECTION MANDIBLE FLOOR OF MOUTH AND TONGUE:

SQUAMOUS CARCINOMA INVADING BONE
Bone margins: Negative for carcinoma

Entire report and diagnosis completed by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file bbc51f88-d4ed-40ac-a526-1366fac2d6f8 (TCGA-CV-A6JU.720B796D-5AF6-43AA-8484-08DEA7CFB133.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).